Gene-level copy-number profile of tumor specimen TARGET-10-PARLJA-09A from TARGET case TARGET-10-PARLJA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.6 years (3,151 days).
Specimen TARGET-10-PARLJA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.df74fbda-a6ca-5b7a-9bfd-f581969e54f1.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARLJA-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate.
https://portal.gdc.cancer.gov/files/9d94b682-e7f6-473a-a1a4-5d2c5b3874d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,749; copy number 1: 643; copy number 2: 56,549; copy number 3: 317; copy number 5: 7; copy number 6: 1; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 369 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr2:197,250,858–197,302,519, 1 gene (within-gene range 0–1): ANKRD44-IT1.
- chr3:143,123,362–143,177,617, 2 genes (within-gene range 0–2): AC018450.1, PBX2P1.
- chr5:178,840,097–178,842,235, 2 genes: AC126915.1, AC126915.3.
- chr7:38,256,337–38,311,808, 9 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:142,328,297–142,802,748, 79 genes (broad region; genes not listed).
- chr8:59,119,040–59,456,010, 3 genes (within-gene range 0–2): AC090152.1, AC087698.1, RNA5SP267.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes: AL449423.1, CDKN2B.
- chr11:32,387,775–32,435,564, 1 gene (within-gene range 0–2): WT1.
- chr13:44,369,365–44,405,984, 3 genes: AL138960.1, SERP2, TUSC8.
- chr13:44,432,144–44,432,678, 1 gene: AL138960.2.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–2): RB1.
- chr13:48,389,567–48,578,088, 7 genes (within-gene range 0–2): LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr14:21,287,939–22,552,156, 158 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,592,676–106,875,071, 47 genes: IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV3-69-1, IGHV1-69-2, AC245369.21, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV4-80, IGHV7-81.
- chr17:3,088,484–3,266,541, 9 genes (within-gene range 0–1): OR1D2, OR1E3, OR1G1, AC090282.1, OR1P1, OR1A2, OR1A1, OR1D4, OR1D3P.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr20:33,316,869–33,329,969, 1 gene (within-gene range 0–2): BPIFB5P.
- chr21:32,538,299–32,538,434, 1 gene: AP000272.1.
- chr22:21,957,025–22,224,566, 33 genes (within-gene range 0–2): TOP3B, PRAMENP, IGLVI-70, IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,344,031–53,365,473, 1 gene, copy number 5 (within-gene range 2–5): AC119428.2.
- chr1:53,366,656–53,368,245, 1 gene, copy number 5: LINC02812.
- chr3:165,772,904–166,161,968, 5 genes, copy number 5 (within-gene range 2–5): BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38.
- chr13:59,262,680–59,263,391, 1 gene, copy number 6: RPP40P2.
- chr17:46,035,313–46,035,770, 1 gene, copy number 7: CR936218.1.

Autosomal genes at a single copy (total copy number 1): 633. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
